Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24S, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24S-01A (Primary Tumor).

UUID: C0A8A457-8790-4745-BD5D-AFBES5254A1C

Final Diagnosis

Breast, right, wide local excision: Infiltrating ductal carcinoma, Nottingham grade II (of III) [tubules 3/3, nuclei 2/3, mitoses 1/3, Nottingham score 6/9], forming a 1.3 x 1.1 x 1.0 cm mass. Ductal carcinoma in situ is absent. An intramammary lymph node present is negative for metastatic carcinoma. Angiolymphatic invasion is absent. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. Biopsy site changes present. All surgical resection margins are negative for tumor (minimum tumor free margin, 0.5 cm, deep margin). (AJCCpT1c)

Lymph nodes, right axillary sentinel, excision: Multiple (2) sentinel lymph nodes are negative for metastatic carcinoma [AJCC pN0(i-)(sn)]. Blue dye is identified in sentinel lymph node No. 1 only. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

Lymph node, right intramammary, excision: A single intramammary lymph node is negative for metastatic carcinoma.

Lymph node, right axillary, excision: A single right axillary lymph node is negative for metastatic carcinoma.

HER2/neu ordered.

1CD-0-3

carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9
4/25/11

Source: NCI Genomic Data Commons file 59a9c2d7-7e5b-4cb0-89ff-12ec250f41db (TCGA-AR-A24S.C0A8A457-8790-4745-BD5D-AFBE55254A1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).